Somatic mutation profile of tumor specimen TCGA-AA-3663-01A (aliquot TCGA-AA-3663-01A-01D-1719-10) from TCGA case TCGA-AA-3663, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage II; Age at diagnosis: 42.9 years (15,675 days).
Specimen TCGA-AA-3663-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c528c76-d1ae-4ec9-b578-bb426561c1f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3663-11A (Solid Tissue Normal), aliquot TCGA-AA-3663-11A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1f8bb58-290e-4b6c-a949-0613468b5c91

The open-access MAF lists 2,308 somatic variants for this specimen: 1,792 protein-altering or splice-affecting, 471 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,257, Silent 471, Frame Shift Del 335, Frame Shift Ins 66, Nonsense Mutation 56, Splice Site 45, Splice Region 22, Intron 19, RNA 9, In Frame Del 9, 5'Flank 7, 3'UTR 4.

Variants (750 of 2,308; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as rs183276875, CM034723; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 28/56 reads (50%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BEST1 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267606679, CM087279, COSV57120460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDC42 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1553196539, COSV59661824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 60/124 reads (48%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- COL3A1 | c.536del p.P179Qfs*43 | Frame Shift Del (DEL) | VAF 26/262 reads (10%) | catalogued as rs1553507180; ClinVar: pathogenic; called by mutect2, pindel
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 189/233 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- DGKE | c.610del p.T204Qfs*6 | Frame Shift Del (DEL) | VAF 100/250 reads (40%) | catalogued as rs147972030; ClinVar: pathogenic; called by mutect2, varscan2
- DMD | c.3713del p.K1238Rfs*6 | Frame Shift Del (DEL) | VAF 127/220 reads (58%) | catalogued as rs1557362198; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 43/123 reads (35%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FGFR2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 32/93 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747502397, COSV60645207, COSV60646793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAMT | c.491dup p.V165Rfs*26 | Frame Shift Ins (INS) | VAF 36/115 reads (31%) | catalogued as rs749390953; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 54/70 reads (77%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.1623dup p.K542Qfs*5 | Frame Shift Ins (INS) | VAF 78/204 reads (38%) | catalogued as rs782077721; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 169/428 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- QARS1 | c.1387C>T p.R463* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as rs755674457, CM1412992, COSV100070040; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 25/49 reads (51%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, varscan2
- TRMU | c.880del p.R294Gfs*12 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | catalogued as rs1490906786; ClinVar: likely pathogenic; called by mutect2, varscan2
- WAS | c.1058del p.P353Hfs*92 | Frame Shift Del (DEL) | VAF 174/379 reads (46%) | catalogued as rs1557007165; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADAC | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51759010; called by muse, mutect2, varscan2
- ABCA13 | c.9933A>C p.K3311N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71286407; called by muse, mutect2, varscan2
- ABCA5 | c.1783G>A p.V595M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1180953651, COSV67016479; called by muse, mutect2, varscan2
- ABCA7 | c.5273T>C p.L1758P | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV54027986; called by muse, mutect2, varscan2
- ABCB8 | c.570G>C p.E190D (on ENST00000297504 / NM_001282291.2; = p.E173D on NM_007188.5) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as COSV52503878; called by muse, mutect2, varscan2
- ABCE1 | c.347A>T p.K116M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56846951; called by muse, mutect2, varscan2
- ABCE1 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.03); catalogued as COSV56846960; called by muse, mutect2, varscan2
- ABCF1 | c.552A>C p.K184N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV58228810; called by muse, mutect2, varscan2
- ABCG4 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 113/277 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56643275, COSV56643566; called by muse, mutect2, varscan2
- AC018630.4 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs373379068; called by muse, mutect2
- ACACB | c.3922A>G p.S1308G | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV100622892, COSV100623307; called by muse, mutect2
- ACACB | c.4174G>A p.V1392M | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs528800239, COSV58132690; called by muse, mutect2, varscan2
- ACD | c.1405C>T p.R469W (on ENST00000620338; = p.R380W on NM_022914.3) | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747913250, COSV54667057; called by muse, mutect2, varscan2
- ACHE | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV53816884; called by muse, mutect2, varscan2
- ACOT12 | c.1263-1G>T p.X421_splice | Splice Site (SNP) | VAF 33/71 reads (46%) | catalogued as COSV56894430; called by muse, mutect2, varscan2
- ACOT7 | c.659C>A p.P220Q (on ENST00000377855 / NM_181864.3; = p.P210Q on NM_007274.4) | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV64113043; called by muse, mutect2, varscan2
- ACTB | c.363+2T>C p.X121_splice | Splice Site (SNP) | VAF 20/291 reads (7%) | catalogued as COSV59318109; called by muse, mutect2
- ACTRT2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65759220; called by muse, mutect2, varscan2
- ACTRT2 | c.1005dup p.D336Rfs*18 | Frame Shift Ins (INS) | VAF 52/145 reads (36%) | catalogued as rs1159784582; called by mutect2, pindel, varscan2
- ADA | c.824A>G p.D275G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV100596124; called by muse, mutect2
- ADAM10 | c.199C>A p.H67N | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53051044; called by muse, varscan2
- ADAM15 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55126314; called by muse, mutect2, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 55/144 reads (38%) | catalogued as rs546931496; called by mutect2, varscan2
- ADAM7 | c.1657G>T p.D553Y | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51536365, COSV51538629; called by muse, mutect2, varscan2
- ADAMTS18 | c.911A>G p.K304R | Missense Mutation (SNP) | VAF 114/395 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV51405238; called by muse, mutect2, varscan2
- ADAMTS2 | c.2210-2del p.X737_splice | Splice Site (DEL) | VAF 40/127 reads (31%) | catalogued as rs1219329381; called by mutect2, pindel, varscan2
- ADAMTS4 | c.472dup p.A158Gfs*2 | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | catalogued as rs1558077955; called by mutect2, pindel
- ADAMTS5 | c.2306C>T p.T769I | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.761); catalogued as rs1178268232, COSV99537602; called by muse, mutect2
- ADAMTS8 | c.1858del p.R620Gfs*23 | Frame Shift Del (DEL) | VAF 42/155 reads (27%) | catalogued as COSV57291705; called by mutect2, pindel, varscan2
- ADAMTSL3 | c.2098A>G p.T700A | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.106); catalogued as COSV99718820; called by muse, varscan2
- ADCY1 | c.3103T>G p.F1035V | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV52033421; called by muse, mutect2, varscan2
- ADCY2 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208528939, COSV57868935; called by muse, mutect2, varscan2
- ADCY4 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs199640938, COSV60253696; called by muse, mutect2, varscan2
- ADCY6 | c.3325A>G p.N1109D | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV57171081; called by muse, mutect2, varscan2
- ADCY6 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 95/253 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV57167483; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB2 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57071084; called by muse, mutect2, varscan2
- ADGRL2 | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54663757; called by muse, mutect2, varscan2
- ADGRL2 | c.3430G>A p.V1144M (on ENST00000370717 / NM_001366005.1; = p.V1131M on NM_012302.4) | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54663793; called by muse, mutect2
- ADGRV1 | c.392G>T p.R131M | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV67983559; called by muse, mutect2, varscan2
- ADORA1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs750446791, COSV55142028; called by muse, mutect2, varscan2
- ADRA1A | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs1250383956, COSV52362169; called by muse, mutect2, varscan2
- ADRA1D | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as rs1468973646, COSV65240633, COSV65241931; called by muse, mutect2, varscan2
- AFDN | c.4466C>T p.T1489M | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1380356396, COSV60042993; called by muse, mutect2, varscan2
- AGFG2 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV53544853; called by muse, mutect2, varscan2
- AGO3 | c.2278A>G p.T760A | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1263448049, COSV55792873; called by muse, mutect2, varscan2
- AGO4 | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751529574, COSV100942951; called by muse, mutect2, varscan2
- AHNAK2 | c.10835A>C p.K3612T | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs772554019, COSV60913608; called by muse, mutect2, varscan2
- AKAP10 | c.1038A>G p.I346M | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs778214457, COSV56730789; called by muse, mutect2, varscan2
- AKAP11 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50295805; called by muse, mutect2, varscan2
- AKAP8L | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV68473246; called by muse, mutect2, varscan2
- ALDH2 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55666559; called by muse, mutect2, varscan2
- ALDH7A1 | c.814T>C p.F272L | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV68628968; called by muse, mutect2, varscan2
- ALK | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV66565340; called by mutect2, varscan2
- ALOX15B | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV66479334; called by muse, mutect2, varscan2
- ALPL | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 150/382 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs748874853, COSV66379757; called by muse, mutect2, varscan2
- AMER1 | c.785T>C p.M262T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV57659376; called by muse, mutect2, varscan2
- AMMECR1L | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs200323463, COSV55760409; called by muse, mutect2, varscan2
- AMPD1 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV62415770; called by muse, mutect2, varscan2
- AMPD2 | c.1148C>A p.A383E | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV56647264; called by muse, mutect2, varscan2
- AMPD2 | c.1997A>G p.Q666R | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56647285; called by muse, mutect2, varscan2
- AMZ2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs375421911; called by muse, mutect2
- ANAPC1 | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 62/532 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV61975626; called by muse, mutect2
- ANKAR | c.1020T>A p.S340R | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55611777; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7750del p.L2584Cfs*43 | Frame Shift Del (DEL) | VAF 39/124 reads (31%) | catalogued as rs768378604; called by mutect2, pindel, varscan2
- ANKLE1 | c.1877A>G p.Y626C (on ENST00000394458; = p.Y572C on NM_152363.6) | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1429306970, COSV101082266; called by muse, mutect2
- ANKRD22 | c.133A>C p.I45L | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV64236360; called by muse, mutect2
- ANKRD26 | c.206G>T p.R69M | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV101066752, COSV65793910; called by muse, mutect2
- ANKRD52 | c.1355G>T p.R452M | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV57283820; called by muse, mutect2, varscan2
- ANKRD6 | c.2016del p.F672Lfs*34 (on ENST00000339746 / NM_001242809.2; = p.F667Lfs*34 on NM_014942.4) | Frame Shift Del (DEL) | VAF 41/119 reads (34%) | catalogued as rs751514998, COSV100329734; called by mutect2, pindel, varscan2
- ANKS1A | c.2545-2A>G p.X849_splice | Splice Site (SNP) | VAF 87/238 reads (37%) | catalogued as rs1436480815, COSV64460127; called by muse, mutect2, varscan2
- ANKS6 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as rs1333301505, COSV62049982; called by muse, mutect2, varscan2
- ANXA10 | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63738787; called by muse, mutect2, varscan2
- ANXA4 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as rs376382183; called by muse, mutect2, varscan2
- ANXA7 | c.1201G>A p.G401R (on ENST00000372919 / NM_001320880.2; = p.G379R on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs765172371, COSV65823347; called by muse, mutect2, varscan2
- AP2A2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs772196174, COSV59959829; called by muse, mutect2, varscan2
- AP3B1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs367631130; called by muse, mutect2, varscan2
- AP5Z1 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as rs1439707706, COSV62241370; called by muse, mutect2, varscan2
- ARAP3 | c.2528del p.P843Qfs*72 | Frame Shift Del (DEL) | VAF 102/267 reads (38%) | catalogued as rs1286143522; called by mutect2, pindel, varscan2
- ARFIP2 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 46/103 reads (45%) | catalogued as rs976148032, COSV54446325; called by muse, mutect2, varscan2
- ARHGAP15 | c.1113C>A p.F371L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1421502107, COSV99710671; called by muse, mutect2, varscan2
- ARHGAP17 | c.96T>G p.I32M | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750139572, COSV51506353; called by muse, mutect2, varscan2
- ARHGAP29 | c.3760G>A p.E1254K | Missense Mutation (SNP) | VAF 116/314 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs772383920, COSV53109773; called by muse, mutect2, varscan2
- ARHGAP30 | c.3188G>A p.R1063Q (on ENST00000368013 / NM_001025598.2; = p.R852Q on NM_181720.3) | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.398); catalogued as rs200017624, COSV63515091, COSV63518541; called by muse, mutect2, varscan2
- ARHGEF15 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.011); catalogued as rs200188980, COSV62724957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF18 | c.3160G>A p.G1054S (on ENST00000359920 / NM_001130955.2; = p.G950S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs567452162, COSV100149524, COSV60469136; ClinVar: uncertain significance; called by muse, varscan2
- ARHGEF2 | c.1139T>C p.V380A (on ENST00000361247 / NM_001162383.2; = p.V352A on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV58109952; called by muse, mutect2, varscan2
- ARHGEF3 | c.1325A>G p.N442S | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV56325646, COSV99575098; called by muse, mutect2, varscan2
- ARHGEF7 | c.2510C>T p.A837V (on ENST00000646102 / NM_001354046.1; = p.A621V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV54542143; called by muse, mutect2, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 44/118 reads (37%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARMC9 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 119/394 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369095745; called by muse, mutect2, varscan2
- ARMH3 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV64234418; called by muse, mutect2, varscan2
- ARRDC2 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320540486, COSV55844201; called by muse, mutect2, varscan2
- ARSG | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV101477894, COSV71592874; called by muse, mutect2
- ARVCF | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as COSV54266338; called by muse, mutect2, varscan2
- ASH1L | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 54/646 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs1416735817, COSV64207287; called by muse, mutect2
- ASIC3 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV52503897; called by muse, mutect2, varscan2
- ASPRV1 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57227894; called by muse, mutect2, varscan2
- ATAD5 | c.4952A>G p.E1651G | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100429958; called by muse, varscan2
- ATCAY | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV56655427; called by muse, mutect2
- ATF4 | c.305T>C p.I102T | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57478617; called by muse, mutect2, varscan2
- ATF6B | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV64322422; called by muse, mutect2, varscan2
- ATG2B | c.6119T>C p.V2040A | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99952051; called by muse, varscan2
- ATG2B | c.5363G>T p.G1788V | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV55890078; called by muse, varscan2
- ATIC | c.545C>G p.T182R | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52692736, COSV52695749; called by muse, mutect2, varscan2
- ATP13A2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 87/314 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV58699886; called by muse, mutect2, varscan2
- ATP1B2 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs765289769, COSV51515412; called by muse, mutect2, varscan2
- ATP2A3 | c.2976G>A p.M992I | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59228328, COSV59229081; called by muse, mutect2, varscan2
- ATP2C1 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD147339, COSV60755439; called by muse, mutect2, varscan2
- ATP4A | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs929702152, COSV52867389; called by muse, varscan2
- ATP8B2 | c.2189A>G p.E730G (on ENST00000672630; = p.E697G on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.557); catalogued as COSV59245680; called by muse, varscan2
- ATRN | c.1013A>C p.K338T | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV53526814; called by muse, mutect2, varscan2
- AVIL | c.1092T>C p.I364= | Splice Region (SNP) | VAF 36/180 reads (20%) | catalogued as rs544964496, COSV99142380; called by muse, varscan2
- AZIN1 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV61479333; called by muse, mutect2, varscan2
- BABAM2 | c.488dup p.N163Kfs*6 | Frame Shift Ins (INS) | VAF 35/117 reads (30%) | catalogued as rs373964958; called by mutect2, varscan2
- BAG6 | c.2965del p.Q989Sfs*85 (on ENST00000676571; = p.Q942Sfs*85 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/113 reads (27%) | catalogued as rs778695310; called by mutect2, pindel, varscan2
- BAIAP2L1 | c.1307del p.P436Hfs*60 | Frame Shift Del (DEL) | VAF 33/99 reads (33%) | catalogued as rs1405664842, COSV50055281; called by mutect2, pindel, varscan2
- BAZ1B | c.3559T>C p.C1187R | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59990554; called by muse, mutect2, varscan2
- BBOX1 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54190595; called by muse, mutect2, varscan2
- BCAR3 | c.2218A>G p.M740V | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV53074379; called by muse, mutect2, varscan2
- BCL6 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as rs776993725, COSV51651367; called by muse, mutect2, varscan2
- BCL9 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200898274; called by muse, mutect2, varscan2
- BCL9L | c.3956C>T p.T1319M | Missense Mutation (SNP) | VAF 107/273 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs150852065; called by muse, mutect2, varscan2
- BCL9L | c.3588del p.P1198Lfs*5 | Frame Shift Del (DEL) | VAF 99/282 reads (35%) | catalogued as rs1555172907; called by mutect2, pindel, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 61/146 reads (42%) | catalogued as rs751794665; called by mutect2, varscan2
- BCL9L | c.1442del p.G481Afs*21 | Frame Shift Del (DEL) | VAF 130/398 reads (33%) | catalogued as COSV52685994; called by mutect2, pindel, varscan2
- BDKRB2 | c.1032G>T p.W344C | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV60013402; called by muse, mutect2, varscan2
- BEST4 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64733849; called by muse, mutect2, varscan2
- BICC1 | c.1207A>G p.N403D | Missense Mutation (SNP) | VAF 89/301 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV54063201; called by muse, mutect2, varscan2
- BICC1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1322163846, COSV54063216; called by muse, mutect2, varscan2
- BICD1 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55677977; called by muse, mutect2, varscan2
- BIRC5 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs267605071, COSV56956329; called by muse, mutect2, varscan2
- BMP1 | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202128760, COSV60529663; called by muse, mutect2, varscan2
- BMP3 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 109/229 reads (48%) | catalogued as COSV51083135; called by muse, mutect2, varscan2
- BNIP5 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as rs544243138, COSV71325501; called by muse, mutect2, varscan2
- BOC | c.2951A>G p.H984R | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV99848720; called by muse, mutect2, varscan2
- BPIFB1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53606234; called by muse, mutect2, varscan2
- BPNT1 | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 72/195 reads (37%) | catalogued as COSV59039669; called by muse, mutect2, varscan2
- BRD3 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 156/288 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV100325077; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 44/232 reads (19%) | catalogued as rs763134487; called by mutect2, varscan2
- BRINP1 | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56297825; called by muse, mutect2, varscan2
- BRINP2 | c.1937T>C p.L646P | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64177033; called by muse, mutect2, varscan2
- BRPF1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs755029735, COSV57403970; called by muse, mutect2, varscan2
- BRPF3 | c.3104G>T p.R1035L | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.932); catalogued as COSV60206949; called by muse, mutect2, varscan2
- BRSK1 | c.55del p.H19Tfs*47 | Frame Shift Del (DEL) | VAF 74/247 reads (30%) | catalogued as COSV55333528; called by mutect2, pindel, varscan2
- BSDC1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV61981885; called by muse, mutect2, varscan2
- BTBD3 | c.529A>G p.M177V | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as rs150544423, COSV54778880; called by muse, mutect2, varscan2
- BTN2A2 | c.1476del p.I493Sfs*20 | Frame Shift Del (DEL) | VAF 64/264 reads (24%) | catalogued as rs1561836074; called by mutect2, pindel, varscan2
- C10orf71 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs938833598, COSV60506898; called by muse, mutect2, varscan2
- C10orf90 | c.1731A>C p.E577D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52953509; called by muse, mutect2, varscan2
- C12orf45 | c.196A>G p.S66G | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55012683; called by muse, mutect2, varscan2
- C12orf71 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV70282653; called by muse, mutect2, varscan2
- C14orf39 | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100407615; called by muse, mutect2
- C16orf70 | c.858del p.F286Lfs*19 | Frame Shift Del (DEL) | VAF 27/121 reads (22%) | catalogued as rs772858888; called by mutect2, pindel, varscan2
- C1QTNF2 | c.905A>G p.N302S (on ENST00000393975; = p.N257S on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1435003520, COSV67432627; called by muse, mutect2, varscan2
- C1orf194 | c.103A>G p.T35A (on ENST00000369948 / NM_001245025.3; = p.T23A on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV64049849; called by muse, mutect2
- C7orf31 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs150213134, COSV52217612; called by muse, varscan2
- C7orf31 | c.358del p.S120Vfs*9 | Frame Shift Del (DEL) | VAF 104/250 reads (42%) | catalogued as rs750735753; called by mutect2, varscan2
- C8B | c.301A>G p.N101D | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64777341; called by muse, mutect2, varscan2
- C8orf34 | c.894T>A p.N298K | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV61377380; called by muse, mutect2, varscan2
- C9orf72 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV66154692; called by muse, mutect2, varscan2
- CA4 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56281367; called by muse, mutect2, varscan2
- CACNA1H | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758015873, COSV61985841; called by muse, mutect2
- CACNA1H | c.6096G>T p.R2032S | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV52352597; called by muse, mutect2, varscan2
- CACNA1S | c.4409T>G p.L1470R | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62938756; called by muse, mutect2, varscan2
- CACNA2D1 | c.2589T>A p.N863K (on ENST00000356253 / NM_001366867.1; = p.N851K on NM_000722.4) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV62377658; called by muse, mutect2, varscan2
- CACNA2D4 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV54948665; called by muse, mutect2, varscan2
- CADPS | c.3460A>G p.M1154V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV51876064; called by muse, mutect2, varscan2
- CADPS2 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs368114197; called by muse, mutect2, varscan2
- CALHM2 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV99588608; called by muse, mutect2
- CAMK2D | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV56429148; called by muse, mutect2, varscan2
- CAMK2G | c.712T>C p.W238R | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59481343; called by muse, mutect2, varscan2
- CAND1 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV73389524; called by muse, mutect2, varscan2
- CAPN5 | c.1465T>A p.S489T (on ENST00000456580; = p.S449T on NM_004055.5) | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.673); catalogued as COSV53687305; called by muse, mutect2, varscan2
- CARD16 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV65212930; called by muse, mutect2
- CASKIN2 | c.1016del p.P339Rfs*95 | Frame Shift Del (DEL) | VAF 72/158 reads (46%) | catalogued as COSV100050703; called by mutect2, varscan2
- CASP1 | c.370C>T p.P124S (on ENST00000436863 / NM_033292.4; = p.P103S on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs199932541, COSV62056326; called by muse, mutect2, varscan2
- CASS4 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as rs1268203172, COSV64386079; called by muse, mutect2, varscan2
- CBLL1 | c.1402G>T p.G468C | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56028696; called by muse, mutect2, varscan2
- CC2D1A | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV58782647; called by muse, varscan2
- CC2D1B | c.2374G>C p.D792H | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52559888; called by muse, mutect2, varscan2
- CC2D2B | c.905A>G p.H302R | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60357756; called by muse, mutect2, varscan2
- CCDC117 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 176/480 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs1283060098, COSV50770730, COSV99968965; called by muse, mutect2, varscan2
- CCDC121 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 151/534 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.038); catalogued as rs1474061062, COSV53114254; called by muse, mutect2, varscan2
- CCDC138 | c.1025T>C p.V342A | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV54566474; called by muse, mutect2, varscan2
- CCDC148 | c.492C>A p.D164E | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.024); catalogued as COSV51758822; called by muse, mutect2
- CCDC151 | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV62697710; called by muse, mutect2, varscan2
- CCDC38 | c.1352A>G p.D451G | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60182727, COSV60182848; called by muse, mutect2, varscan2
- CCDC87 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV59578814; called by muse, mutect2, varscan2
- CCDC88B | c.1265T>C p.L422P | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57265759; called by muse, mutect2, varscan2
- CCDC88C | c.3026C>T p.T1009I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66237253, COSV66239021; called by muse, mutect2
- CCDC9B | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66875196; called by muse, mutect2, varscan2
- CCER1 | c.1185G>T p.Q395H | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV62646570; called by muse, mutect2, varscan2
- CCKBR | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 287/940 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs755245323, COSV58100685; called by muse, mutect2, varscan2
- CCN2 | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63466638; called by muse, mutect2, varscan2
- CCNB3 | c.2632T>C p.S878P | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV52072471, COSV99328415; called by muse, mutect2, varscan2
- CCR5 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 91/237 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs1800939, CM995337, COSV52751421; called by muse, mutect2, varscan2
- CCR7 | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV55849191; called by muse, mutect2, varscan2
- CD163L1 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV58014637; called by muse, mutect2, varscan2
- CD180 | c.1685T>C p.L562P | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.702); catalogued as COSV99842241; called by muse, mutect2, varscan2
- CD1E | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as rs774595737, COSV63770787, COSV63773186; called by muse, mutect2, varscan2
- CD200 | c.705G>T p.K235N (on ENST00000473539 / NM_001004196.3; = p.K210N on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV59863024; called by muse, mutect2, varscan2
- CD200R1L | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs191314755; called by muse, mutect2, varscan2
- CD7 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as rs149247674; called by muse, mutect2
- CDC42BPB | c.4708C>T p.R1570* | Nonsense Mutation (SNP) | VAF 116/307 reads (38%) | catalogued as rs1416279074, COSV63474703; called by muse, mutect2, varscan2
- CDCA7L | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV60952310; called by muse, mutect2, varscan2
- CDH3 | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV50556870; called by muse, mutect2, varscan2
- CDHR2 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1186410007, COSV56137716; called by muse, mutect2, varscan2
- CDK5R1 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.303); catalogued as COSV55578438; called by muse, mutect2
- CDK5RAP2 | c.2376G>A p.R792= | Splice Region (SNP) | VAF 46/172 reads (27%) | catalogued as COSV100575447; called by muse, mutect2, varscan2
- CDR2 | c.850A>G p.K284E | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.027); catalogued as COSV51675995; called by muse, mutect2, varscan2
- CEACAM7 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs374301472; called by muse, mutect2, varscan2
- CEBPA | c.947A>C p.E316A | Missense Mutation (SNP) | VAF 37/372 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57197044; called by muse, mutect2
- CELSR1 | c.3781A>G p.T1261A | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53088198; called by muse, mutect2, varscan2
- CENPF | c.6613C>T p.L2205F | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs754191320, COSV65274319; called by muse, mutect2, varscan2
- CENPJ | c.3223T>C p.S1075P | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV67883312; called by muse, mutect2, varscan2
- CEP104 | c.695A>G p.Y232C | Missense Mutation (SNP) | VAF 127/324 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV100986355; called by muse, mutect2, varscan2
- CEP112 | c.1368G>T p.K456N | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV67138483; called by muse, mutect2, varscan2
- CEP120 | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60265146; called by muse, mutect2, varscan2
- CEP192 | c.3746C>T p.A1249V | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as COSV58062829; called by muse, mutect2, varscan2
- CEP290 | c.7153del p.I2385* | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | catalogued as rs781310385; called by mutect2, pindel, varscan2
- CEP290 | c.1359G>A p.S453= | Splice Region (SNP) | VAF 43/102 reads (42%) | catalogued as rs779195306, COSV58350973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP350 | c.6233G>T p.R2078M | Missense Mutation (SNP) | VAF 135/356 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62601183; called by muse, mutect2, varscan2
- CEP70 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs552389060, COSV53874171; called by muse, mutect2, varscan2
- CEP85L | c.418del p.E140Sfs*6 | Frame Shift Del (DEL) | VAF 146/391 reads (37%) | catalogued as rs776770568, COSV63826036; called by mutect2, pindel, varscan2
- CEPT1 | c.521A>C p.Q174P | Missense Mutation (SNP) | VAF 27/558 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV100853479; called by muse, mutect2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 61/195 reads (31%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFAP157 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 35/127 reads (28%) | catalogued as rs1285910980, COSV58852770; called by muse, mutect2, varscan2
- CFAP20DC | c.2299C>T p.R767C (on ENST00000482387 / NM_001351530.2; = p.R516C on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs772778129, COSV55918830; called by muse, mutect2, varscan2
- CFAP251 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 155/398 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380640665, COSV56609724; called by muse, mutect2, varscan2
- CFAP77 | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); catalogued as rs891275054, COSV58010085; called by muse, mutect2, varscan2
- CHD8 | c.6659G>T p.S2220I (on ENST00000646647 / NM_001170629.2; = p.S1941I on NM_020920.4) | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV63036761; called by muse, mutect2, varscan2
- CHD9 | c.2974C>T p.R992* | Nonsense Mutation (SNP) | VAF 55/127 reads (43%) | catalogued as rs1177159428, COSV54609586; called by muse, mutect2, varscan2
- CHD9 | c.7291del p.R2431Gfs*8 (on ENST00000398510 / NM_001382353.1; = p.R2415Gfs*8 on NM_025134.7) | Frame Shift Del (DEL) | VAF 73/193 reads (38%) | catalogued as rs748826986; called by mutect2, varscan2
- CHI3L1 | c.968A>T p.N323I | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55137811; called by muse, mutect2, varscan2
- CHIT1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.188); catalogued as COSV55146530; called by muse, mutect2, varscan2
- CHL1 | c.2154A>G p.I718M (on ENST00000397491 / NM_001253387.1; = p.I734M on NM_006614.4) | Missense Mutation (SNP) | VAF 102/216 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56591263; called by muse, mutect2, varscan2
- CHRNA9 | c.1208A>G p.D403G | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100038946; called by muse, mutect2, varscan2
- CIB3 | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV54165978; called by muse, mutect2, varscan2
- CIDEC | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100396654, COSV61062645; called by muse, mutect2, varscan2
- CIITA | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV60856394; called by muse, mutect2, varscan2
- CIITA | c.3176T>C p.V1059A | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60856402; called by muse, mutect2, varscan2
- CLASP1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1055573348, COSV55321615; called by muse, mutect2, varscan2
- CLCN2 | c.2491A>G p.T831A | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.238); catalogued as COSV55600625; called by muse, mutect2, varscan2
- CLCNKA | c.655+1G>A p.X219_splice | Splice Site (SNP) | VAF 126/330 reads (38%) | catalogued as COSV58890866, COSV58891250; called by muse, mutect2, varscan2
- CLDN12 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 116/374 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55306683; called by muse, mutect2, varscan2
- CLEC4M | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1054434492, COSV50217873; called by muse, mutect2, varscan2
- CLEC4M | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50217909; called by muse, mutect2, varscan2
- CLHC1 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 84/225 reads (37%) | catalogued as rs199596563, COSV63427127; called by muse, mutect2, varscan2
- CLPTM1L | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745665981, COSV57990197; called by muse, mutect2, varscan2
- CLUH | c.3086T>C p.L1029P (on ENST00000435359; = p.L1068P on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70928469; called by muse, mutect2, varscan2
- CMKLR1 | c.268G>A p.V90I (on ENST00000312143 / NM_001142344.2; = p.V88I on NM_004072.3) | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as rs1303270427, COSV100379420; called by muse, mutect2
- CMTM1 | c.304G>A p.E102K (on ENST00000457188 / NM_181269.3; = p.E219K on NM_052999.4) | Missense Mutation (SNP) | VAF 132/332 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV99216474; called by muse, mutect2, varscan2
- CMYA5 | c.8183T>G p.L2728R | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV71405439; called by muse, mutect2, varscan2
- CNDP2 | c.1416G>T p.Q472H | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60839641; called by muse, mutect2, varscan2
- CNN1 | c.249C>A p.H83Q | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV52955816; called by muse, mutect2, varscan2
- CNOT10 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV100094469; called by muse, mutect2
- CNOT6 | c.464A>C p.D155A | Missense Mutation (SNP) | VAF 132/363 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV56161064; called by muse, mutect2, varscan2
- CNPY1 | c.241+2T>C p.X81_splice | Splice Site (SNP) | VAF 32/157 reads (20%) | catalogued as COSV58787193; called by muse, mutect2, varscan2
- CNTN1 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 34/125 reads (27%) | catalogued as rs1348891874, COSV61638892; called by muse, mutect2, varscan2
- CNTN4 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV61871564; called by muse, mutect2, varscan2
- CNTROB | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as COSV58050137; called by muse, mutect2, varscan2
- COL12A1 | c.8561G>A p.G2854D | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59394248; called by muse, mutect2, varscan2
- COL1A1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs777644312, COSV56804172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL25A1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.087); catalogued as COSV67649323; called by muse, mutect2, varscan2
- COL26A1 | c.583A>G p.R195G (on ENST00000313669 / NM_001278563.3; = p.R193G on NM_133457.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV100561764; called by muse, mutect2, varscan2
- COL2A1 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1049950456, COSV61529793; called by muse, mutect2, varscan2
- COL3A1 | c.3605C>T p.A1202V | Missense Mutation (SNP) | VAF 101/344 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV58586115; called by muse, mutect2, varscan2
- COL3A1 | c.4300C>T p.R1434C | Missense Mutation (SNP) | VAF 103/262 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs747324731, COSV58586131, COSV58591395; ClinVar: uncertain significance; called by muse, varscan2
- COL4A4 | c.3684del p.G1230Vfs*58 | Frame Shift Del (DEL) | VAF 39/115 reads (34%) | catalogued as rs1348572523, CD1414071, COSV61631407; called by mutect2, pindel, varscan2
- COL4A5 | c.271A>T p.I91F | Missense Mutation (SNP) | VAF 127/174 reads (73%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.856); catalogued as COSV60360164; called by muse, varscan2
- COL5A1 | c.1569+1G>A p.X523_splice | Splice Site (SNP) | VAF 26/82 reads (32%) | catalogued as COSV65668094, COSV65674250; called by muse, varscan2
- COL5A1 | c.2488dup p.X830_splice | Splice Site (INS) | VAF 30/173 reads (17%) | catalogued as rs753218679; called by mutect2, pindel, varscan2
- COL5A2 | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100880327; called by muse, mutect2
- COL5A3 | c.3143del p.P1048Lfs*96 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs771976753; called by mutect2, varscan2
- COL6A6 | c.5992A>G p.T1998A | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV62023055; called by muse, mutect2
- COL7A1 | c.3299A>G p.H1100R | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); catalogued as rs1466066197, COSV60394392; called by muse, mutect2, varscan2
- COL9A1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs778243284, COSV61828847; called by muse, mutect2, varscan2
- COPB1 | c.1985A>G p.N662S | Missense Mutation (SNP) | VAF 97/253 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1333715949, COSV51447909; called by muse, mutect2, varscan2
- COQ9 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV52645599; called by muse, mutect2, varscan2
- CPA3 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56044075; called by muse, mutect2, varscan2
- CPLANE1 | c.8793T>G p.N2931K | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV99950559; called by muse, mutect2
- CPN2 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV60470159, COSV60470236; called by muse, mutect2, varscan2
- CPNE8 | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV58841852; called by muse, mutect2
- CPSF2 | c.1654del p.I552Sfs*5 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | catalogued as rs758712860; called by mutect2, pindel, varscan2
- CPVL | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55301641; called by muse, mutect2, varscan2
- CRACD | c.2383C>A p.L795I | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51719599; called by muse, mutect2, varscan2
- CREB1 | c.882-1G>T p.X294_splice (on ENST00000432329 / NM_134442.5; = p.X280_splice on NM_004379.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/100 reads (13%) | catalogued as COSV62064522; called by muse, mutect2, varscan2
- CREBRF | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1205017616, COSV51632670; called by muse, mutect2, varscan2
- CRHR1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs778136105, COSV53277813, COSV99524345; called by muse, mutect2, varscan2
- CRHR2 | c.329A>T p.D110V | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV59264827; called by muse, varscan2
- CROCC | c.4669C>T p.Q1557* | Nonsense Mutation (SNP) | VAF 59/133 reads (44%) | catalogued as COSV65011559; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYBA1 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56600739; called by muse, mutect2, varscan2
- CRYBA1 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56600746; called by muse, mutect2, varscan2
- CRYBG3 | c.7152+2T>C p.X2384_splice | Splice Site (SNP) | VAF 43/119 reads (36%) | catalogued as COSV99477003; called by muse, mutect2, varscan2
- CRYL1 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767757127, COSV53417825; called by muse, mutect2, varscan2
- CSF1R | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as rs1463432282, COSV53833404; called by muse, varscan2
- CSMD1 | c.8544G>A p.W2848* (on ENST00000520002; = p.W2847* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as COSV59312172; called by muse, mutect2, varscan2
- CSMD1 | c.5723A>G p.Y1908C (on ENST00000520002; = p.Y1907C on NM_033225.6) | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100147852; called by muse, mutect2
- CSMD1 | c.1826T>C p.M609T (on ENST00000520002; = p.M608T on NM_033225.6) | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59312238; called by muse, mutect2, varscan2
- CSMD1 | c.949T>G p.L317V | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV101227511, COSV68173437; called by muse, mutect2
- CSMD2 | c.10390C>T p.R3464C | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs376862875; called by muse, mutect2, varscan2
- CSMD2 | c.5143G>A p.A1715T | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs529128430, COSV53903887; called by muse, mutect2, varscan2
- CSMD3 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); catalogued as COSV99834365; called by muse, mutect2
- CSN3 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59243946; called by muse, mutect2, varscan2
- CSN3 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV59243956; called by muse, mutect2, varscan2
- CSPP1 | c.520C>T p.R174C (on ENST00000676605; = p.R133C on NM_024790.6) | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs374169543, COSV51583375; called by muse, mutect2, varscan2
- CST1 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 84/218 reads (39%) | catalogued as rs756924682; called by mutect2, varscan2
- CTBP1 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 98/264 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52073341; called by muse, mutect2, varscan2
- CTC1 | c.2933G>T p.R978I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59853015; called by muse, mutect2, varscan2
- CTNND1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV62383142; called by muse, mutect2, varscan2
- CTR9 | c.3200G>A p.G1067D | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV63728413; called by muse, varscan2
- CTSC | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.117); catalogued as COSV99910675; called by muse, mutect2
- CTTNBP2 | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 112/301 reads (37%) | catalogued as COSV50428280, COSV99353953; called by muse, mutect2, varscan2
- CUBN | c.2566C>A p.L856I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV64713927; called by muse, varscan2
- CUL7 | c.3769G>A p.G1257S | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs769005642, COSV54815657; ClinVar: uncertain significance; called by muse, varscan2
- CUL7 | c.3743G>A p.C1248Y | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV54815684; called by muse, varscan2
- CUL9 | c.4799A>G p.Y1600C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52727729; called by muse, mutect2
- CUX2 | c.4286dup p.A1430Cfs*11 | Frame Shift Ins (INS) | VAF 30/129 reads (23%) | catalogued as rs750550645; called by mutect2, varscan2
- CXCR4 | c.338A>G p.H113R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV54011795; called by muse, mutect2, varscan2
- CYBC1 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV60063700; called by muse, mutect2, varscan2
- CYP26A1 | c.1066A>C p.I356L | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56417873; called by muse, mutect2, varscan2
- CYP2D6 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs774382844, COSV62243757; called by muse, mutect2, varscan2
- CZIB | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as rs777017649, COSV99598138; called by muse, mutect2, varscan2
- DAAM2 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 80/238 reads (34%) | catalogued as rs925350528, COSV51310425; called by muse, mutect2, varscan2
- DAB1 | c.1632G>T p.E544D (on ENST00000371231; = p.E511D on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.108); catalogued as COSV64692327; called by muse, mutect2, varscan2
- DAW1 | c.794G>A p.S265N | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1490537587, COSV59364858; called by muse, mutect2, varscan2
- DBF4 | c.74dup p.N25Kfs*11 | Frame Shift Ins (INS) | VAF 17/40 reads (43%) | catalogued as rs762918884; called by mutect2, varscan2
- DBR1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99604515; called by muse, mutect2
- DCAF7 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV60407317; called by muse, mutect2
- DCLK2 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV56202851; called by muse, mutect2, varscan2
- DDX21 | c.1255C>A p.H419N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100826498, COSV62555596; called by muse, mutect2, varscan2
- DDX39A | c.670A>G p.M224V | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV54391281; called by muse, mutect2, varscan2
- DDX60 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 143/412 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as rs142942424; called by muse, mutect2, varscan2
- DDX60L | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs767852528, COSV52712156; called by muse, mutect2, varscan2
- DENND4B | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as rs373534970, COSV57842243; called by muse, mutect2
- DENND5A | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760981468, COSV60233064; called by muse, mutect2, varscan2
- DENND5B | c.1451T>A p.L484* | Nonsense Mutation (SNP) | VAF 88/212 reads (42%) | catalogued as COSV60901962; called by muse, mutect2, varscan2
- DESI2 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV55640869; called by muse, mutect2, varscan2
- DGAT1 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60047578; called by muse, mutect2, varscan2
- DHDDS | c.503A>T p.E168V | Missense Mutation (SNP) | VAF 111/309 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as COSV52576285; called by muse, mutect2, varscan2
- DHFR2 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 120/339 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58935027; called by muse, mutect2, varscan2
- DHX29 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748716619, COSV52417871; called by muse, mutect2, varscan2
- DHX36 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV57672057; called by muse, mutect2, varscan2
- DIDO1 | c.4216C>T p.R1406W | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1462994165, COSV56619911; called by muse, mutect2
- DIP2A | c.4612G>T p.G1538W | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59476215; called by muse, mutect2, varscan2
- DISP3 | c.4162G>T p.A1388S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533939192, COSV53821519; called by muse, mutect2, varscan2
- DLEC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV57298540; called by muse, mutect2, varscan2
- DLEC1 | c.4340T>C p.L1447P | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV57298568; called by muse, mutect2, varscan2
- DLG2 | c.192T>G p.I64M | Missense Mutation (SNP) | VAF 25/395 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1247938717, COSV65884465; called by muse, mutect2
- DLGAP1 | c.1898C>T p.T633I | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100230766; called by muse, mutect2
- DLL1 | c.1802A>T p.D601V | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV64537252; called by muse, mutect2, varscan2
- DMAC2L | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55413244; called by muse, mutect2, varscan2
- DNAH1 | c.11017C>A p.L3673I | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.873); catalogued as COSV70228318; called by muse, mutect2, varscan2
- DNAH12 | c.1209C>A p.N403K | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV100244513; called by muse, mutect2
- DNAH17 | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 113/275 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs151028921; called by muse, mutect2, varscan2
- DNAH2 | c.9019C>G p.L3007V | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV66718674; called by muse, mutect2, varscan2
- DNAH5 | c.1644+1G>A p.X548_splice | Splice Site (SNP) | VAF 49/99 reads (49%) | catalogued as COSV99449757; called by muse, mutect2, varscan2
- DNAH7 | c.3221del p.L1074Cfs*23 | Frame Shift Del (DEL) | VAF 59/166 reads (36%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAH8 | c.3028T>C p.Y1010H | Missense Mutation (SNP) | VAF 135/353 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100545288; called by muse, mutect2, varscan2
- DNAJA4 | c.830C>T p.T277M (on ENST00000343789; = p.T306M on NM_018602.3) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); catalogued as rs765263538, COSV59425399; called by muse, mutect2, varscan2
- DNAJC13 | c.5001T>C p.G1667= | Splice Region (SNP) | VAF 20/202 reads (10%) | catalogued as COSV53449238; called by muse, mutect2
- DNAJC16 | c.1794del p.G599Afs*5 | Frame Shift Del (DEL) | VAF 33/103 reads (32%) | catalogued as rs756910133; called by mutect2, pindel, varscan2
- DNASE2B | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs191605025; called by muse, mutect2, varscan2
- DNPEP | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781324438, COSV56110659; called by muse, mutect2, varscan2
- DOC2A | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs775797559, COSV58751145; called by muse, varscan2
- DOCK10 | c.5743A>G p.K1915E | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV99289484; called by muse, mutect2
- DOCK2 | c.3008C>T p.A1003V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56954174; called by muse, mutect2, varscan2
- DOCK2 | c.3611C>T p.T1204I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV56954187; called by muse, mutect2, varscan2
- DOCK3 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 154/381 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1228911523, COSV56516212; called by muse, mutect2, varscan2
- DOCK3 | c.3486A>G p.L1162= | Splice Region (SNP) | VAF 19/55 reads (35%) | catalogued as rs764740642, COSV56516230; called by muse, mutect2, varscan2
- DOCK7 | c.1273A>G p.S425G | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99224409; called by muse, mutect2, varscan2
- DOCK8 | c.2258T>C p.V753A | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1357009517, COSV66619499; called by muse, mutect2, varscan2
- DOP1A | c.3089A>G p.E1030G | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99381896; called by muse, mutect2, varscan2
- DOP1B | c.2541del p.F847Lfs*7 | Frame Shift Del (DEL) | VAF 42/264 reads (16%) | catalogued as rs750520568; called by mutect2, pindel, varscan2
- DOP1B | c.6475G>T p.A2159S | Missense Mutation (SNP) | VAF 29/357 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.279); catalogued as COSV67693042; called by muse, mutect2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 59/164 reads (36%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DPP10 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.405); catalogued as rs867892663, COSV59661594, COSV59680975; called by muse, mutect2, varscan2
- DPP4 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149643982, COSV62106254; called by muse, mutect2, varscan2
- DPP6 | c.1535G>T p.R512L (on ENST00000377770 / NM_001364500.2; = p.R450L on NM_001936.5) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59598846, COSV59608372; called by muse, mutect2, varscan2
- DPP9 | c.728C>T p.T243I (on ENST00000598800; = p.T272I on NM_139159.5) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV99506127; called by muse, mutect2
- DPPA2 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.318); catalogued as COSV72118029; called by muse, mutect2, varscan2
- DPPA5 | c.292+2T>C p.X98_splice | Splice Site (SNP) | VAF 32/61 reads (52%) | catalogued as COSV64875478; called by muse, varscan2
- DSCC1 | c.422T>G p.L141R | Missense Mutation (SNP) | VAF 120/357 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV58086865; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 33/59 reads (56%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs746928635; called by mutect2, pindel, varscan2
- DUSP12 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV63411278; called by muse, mutect2, varscan2
- DUSP16 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV53807309; called by muse, mutect2, varscan2
- DUSP8 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV59029908; called by muse, mutect2, varscan2
- DXO | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV61713351; called by muse, mutect2, varscan2
- DYRK1B | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs773857931, COSV59913324; called by muse, mutect2, varscan2
- E2F7 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs370152085; called by muse, mutect2, varscan2
- E2F7 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 123/422 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs779479853, COSV59739166; called by muse, mutect2, varscan2
- EBF1 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV58175383; called by muse, mutect2, varscan2
- EBF2 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV68777221; called by muse, mutect2, varscan2
- EBP | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 128/173 reads (74%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV52141585; called by muse, mutect2, varscan2
- EDARADD | c.176C>T p.T59I (on ENST00000334232 / NM_145861.4; = p.T49I on NM_080738.4) | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as COSV62062283; called by muse, varscan2
- EDC4 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as rs762255664, COSV54645562; called by muse, mutect2, varscan2
- EDEM2 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1434597908, COSV65712873; called by muse, mutect2, varscan2
- EDIL3 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56892697; called by muse, mutect2, varscan2
- EDN3 | c.517del p.C173Afs*36 (on ENST00000337938 / NM_001302455.2; = p.C173Afs*25 on NM_207032.3) | Frame Shift Del (DEL) | VAF 50/146 reads (34%) | catalogued as COSV100285244; called by mutect2, pindel, varscan2
- EDNRB | c.476C>T p.A159V (on ENST00000377211 / NM_001201397.1; = p.A69V on NM_000115.5) | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as rs1019947807, COSV57521619; called by muse, mutect2, varscan2
- EEF1A1 | c.830T>G p.V277G | Missense Mutation (SNP) | VAF 133/612 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV58549381; called by muse, varscan2
- EGR1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53518935; called by muse, mutect2, varscan2
- EIF2AK1 | c.1654A>T p.R552W | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52238485; called by muse, mutect2, varscan2
- EIF2B4 | c.862G>T p.G288C (on ENST00000347454 / NM_001034116.2; = p.G287C on NM_015636.3) | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV52007397; called by muse, mutect2, varscan2
- EIF3A | c.3652_3654del p.E1218del | In Frame Del (DEL) | VAF 214/828 reads (26%) | catalogued as rs972766859; called by pindel, varscan2
- EIF3A | c.1168C>A p.L390I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV64961116; called by muse, mutect2, varscan2
- ELANE | c.67+1del | Frame Shift Del (DEL) | VAF 43/141 reads (30%) | catalogued as rs886039350; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ELAVL3 | c.47dup p.A18Gfs*18 | Frame Shift Ins (INS) | VAF 76/164 reads (46%) | catalogued as rs751148694; called by mutect2, varscan2
- ELOA2 | c.858dup p.Q287Afs*80 | Frame Shift Ins (INS) | VAF 56/192 reads (29%) | catalogued as rs1244859640; called by mutect2, pindel, varscan2
- ELOVL6 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.385); catalogued as COSV56428343; called by muse, mutect2, varscan2
- EMC1 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs994800826, COSV64345630; called by muse, mutect2, varscan2
- EML1 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as rs1488503869, COSV51744010; called by muse, mutect2, varscan2
- EML5 | c.1659G>A p.G553= | Splice Region (SNP) | VAF 12/40 reads (30%) | catalogued as COSV61344545; called by muse, mutect2, varscan2
- ENAH | c.470A>G p.E157G | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV99490659; called by muse, varscan2
- ENAM | c.1577G>T p.R526M | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68535764, COSV68536721; called by muse, mutect2, varscan2
- ENKD1 | c.253T>G p.S85A | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as rs150409822; called by muse, mutect2, varscan2
- EPB41L4B | c.2419-1G>T p.X807_splice | Splice Site (SNP) | VAF 42/137 reads (31%) | catalogued as COSV65802826, COSV99080979; called by muse, mutect2, varscan2
- EPHA1 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 107/257 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51970609; called by muse, mutect2, varscan2
- EPHA7 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65169187; called by muse, mutect2, varscan2
- EPHB3 | c.2501A>G p.Y834C | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759032023, COSV57805438; called by muse, mutect2, varscan2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 46/117 reads (39%) | catalogued as rs756407271; called by mutect2, pindel, varscan2
- EPHX2 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1347152892, COSV66844611; called by muse, mutect2, varscan2
- EPN1 | c.833G>C p.G278A (on ENST00000270460 / NM_001321263.1; = p.G253A on NM_013333.3) | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1303432870, COSV50036022, COSV50036896; called by muse, mutect2, varscan2
- EPN2 | c.1460C>A p.P487H | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59060912; called by muse, mutect2, varscan2
- EPRS1 | c.1580T>C p.M527T | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.396); catalogued as rs753164503, COSV100859390; called by muse, mutect2, varscan2
- EPS15 | c.2069A>G p.H690R | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.108); catalogued as COSV65541765; called by muse, varscan2
- ESR1 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.913); catalogued as COSV99239187; called by muse, mutect2
- ESYT2 | c.2564G>T p.S855I (on ENST00000613624; = p.S779I on NM_020728.3) | Missense Mutation (SNP) | VAF 110/288 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV51750281; called by muse, mutect2, varscan2
- ETAA1 | c.1745A>G p.D582G | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55472726; called by muse, mutect2, varscan2
- ETF1 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as COSV62127246; called by muse, mutect2, varscan2
- EVC | c.1667A>G p.Y556C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.443); catalogued as COSV53831711; called by muse, mutect2, varscan2
- EVC | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV53831719; called by muse, mutect2, varscan2
- EZH1 | c.1875G>T p.W625C | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70549185; called by muse, varscan2
- EZH1 | c.1794G>T p.K598N | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as COSV70549190; called by muse, mutect2, varscan2
- FADS6 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV59602136; called by muse, mutect2, varscan2
- FAM13C | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53252796, COSV99513849; called by muse, mutect2
- FAM171B | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV59002663; called by muse, mutect2, varscan2
- FAM189B | c.854del p.P285Lfs*36 | Frame Shift Del (DEL) | VAF 61/175 reads (35%) | catalogued as COSV56944898; called by mutect2, pindel, varscan2
- FAM50B | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs748727501, COSV66654711; called by muse, mutect2, varscan2
- FANCD2 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.635); catalogued as rs1553610798, COSV55036500; ClinVar: uncertain significance; called by muse, mutect2
- FAT1 | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71673452; called by muse, mutect2, varscan2
- FAT4 | c.5150C>T p.A1717V | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV67884562; called by muse, mutect2, varscan2
- FAT4 | c.14734C>T p.P4912S | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV58680825; called by muse, mutect2, varscan2
- FBH1 | c.2921T>C p.V974A (on ENST00000362091 / NM_178150.3; = p.V1025A on NM_032807.4) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV62982315; called by muse, mutect2, varscan2
- FBXL17 | c.1616T>C p.L539P | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100671365; called by muse, mutect2
- FBXL18 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); catalogued as rs766265655, COSV66666218; called by muse, mutect2, varscan2
- FBXL20 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52898284; called by muse, mutect2, varscan2
- FBXO40 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 109/240 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100573164; called by muse, mutect2, varscan2
- FBXO40 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs755825702, COSV57523498; called by muse, mutect2, varscan2
- FBXO47 | c.1126del p.M376* | Frame Shift Del (DEL) | VAF 44/152 reads (29%) | catalogued as rs1484207207; called by mutect2, pindel, varscan2
- FBXO6 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs746354058, COSV65100413, COSV65100609; called by muse, mutect2, varscan2
- FBXW10 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 91/329 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV57059690; called by muse, mutect2, varscan2
- FCHSD2 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 9/195 reads (5%) | catalogued as COSV60807573; called by muse, mutect2
- FCN3 | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV54641120; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 73/230 reads (32%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FER1L6 | c.1859T>G p.I620S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.03); catalogued as COSV67549461; called by muse, mutect2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 20/32 reads (63%) | catalogued as rs748969702; called by mutect2, varscan2
- FGGY | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1419798465, COSV100364665; called by muse, mutect2, varscan2
- FHL2 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs536715218, COSV59079388; called by muse, mutect2, varscan2
- FIBIN | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV59413640; called by muse, mutect2, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 61/248 reads (25%) | catalogued as rs749851531; called by mutect2, pindel, varscan2
- FLNA | c.5917A>T p.I1973F (on ENST00000369850 / NM_001110556.2; = p.I1965F on NM_001456.3) | Missense Mutation (SNP) | VAF 152/192 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV61041588; called by muse, mutect2, varscan2
- FLNA | c.2252G>A p.G751D | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV61041602; called by muse, mutect2, varscan2
- FLNB | c.5726C>T p.T1909I | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55877245; called by muse, mutect2, varscan2
- FLNC | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs763954095, COSV57950419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT1 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.77); catalogued as COSV55359361; called by muse, mutect2, varscan2
- FLRT1 | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55359372; called by muse, mutect2, varscan2
- FLRT2 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.675); catalogued as COSV58140049; called by muse, mutect2, varscan2
- FLRT2 | c.1016G>A p.C339Y | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58137601, COSV58140060; called by muse, mutect2, varscan2
- FLRT2 | c.1723C>A p.Q575K | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV58140068; called by muse, mutect2, varscan2
- FLT1 | c.2878G>A p.V960I | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs554058758, COSV56725597; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 52/118 reads (44%) | catalogued as rs769482947; called by mutect2, varscan2
- FMNL3 | c.2248A>G p.I750V | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53300859; called by muse, mutect2, varscan2
- FNDC3A | c.2025A>C p.K675N (on ENST00000492622 / NM_001079673.2; = p.K619N on NM_014923.5) | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV68132844; called by muse, mutect2
- FNDC3B | c.1595C>G p.T532S | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV61040828; called by muse, mutect2, varscan2
- FNTA | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56489811; called by muse, mutect2, varscan2
- FOXA2 | c.400A>C p.S134R (on ENST00000377115 / NM_153675.3; = p.S140R on NM_021784.5) | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV65796087; called by muse, mutect2, varscan2
- FOXN1 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56881507; called by muse, mutect2, varscan2
- FOXN3 | c.1306C>T p.P436S (on ENST00000261302; = p.P414S on NM_005197.4) | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs199923188, COSV54307587; called by muse, mutect2, varscan2
- FOXRED2 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.145); catalogued as rs567459414, COSV53399618; called by muse, mutect2, varscan2
- FPR2 | c.536A>T p.N179I | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV60672591; called by muse, mutect2, varscan2
- FRAS1 | c.7025C>T p.T2342I | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs373096695; called by muse, mutect2, varscan2
- FRAS1 | c.7153del p.V2385Sfs*37 | Frame Shift Del (DEL) | VAF 39/159 reads (25%) | catalogued as COSV53619321; called by mutect2, pindel, varscan2
- FREM2 | c.6751A>G p.I2251V | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as COSV99748765; called by muse, mutect2, varscan2
- FRMD6 | c.893G>A p.R298Q (on ENST00000344768 / NM_001267046.2; = p.R290Q on NM_152330.4) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.54); catalogued as rs374142834, COSV100656304; called by muse, mutect2
- FRMPD1 | c.2351del p.P784Rfs*45 | Frame Shift Del (DEL) | VAF 32/133 reads (24%) | catalogued as rs771215197, COSV66701542; called by mutect2, pindel, varscan2
- FRMPD1 | c.4667G>A p.R1556H | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs202028346, COSV66699251; called by muse, mutect2, varscan2
- FRY | c.6840G>A p.W2280* | Nonsense Mutation (SNP) | VAF 50/161 reads (31%) | catalogued as COSV66568735; called by muse, mutect2, varscan2
- FRYL | c.4453A>G p.N1485D | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.936); catalogued as COSV51945132; called by muse, mutect2, varscan2
- FRYL | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV51945146; called by muse, mutect2, varscan2
- FSIP2 | c.16471G>A p.V5491I | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.205); catalogued as rs1229526537, COSV58083658; called by muse, mutect2, varscan2
- FSTL4 | c.2369del p.G790Vfs*6 | Frame Shift Del (DEL) | VAF 34/96 reads (35%) | catalogued as rs765771244; called by mutect2, varscan2
- FTO | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as rs200201735, COSV67111046; called by muse, mutect2, varscan2
- FUBP1 | c.1778T>C p.M593T | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV53929594; called by muse, mutect2, varscan2
- FUBP3 | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV60513856; called by muse, mutect2, varscan2
- FZD7 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1480494909, COSV53809116; called by muse, mutect2, varscan2
- G2E3 | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV52839905; called by muse, mutect2, varscan2
- G3BP1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 132/320 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV62366009; called by muse, mutect2, varscan2
- GABRA6 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50879945; called by muse, mutect2, varscan2
- GABRP | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54665028; called by muse, mutect2
- GAL | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as rs540782765, COSV55763850; called by muse, mutect2
- GARS1 | c.1184C>A p.A395D | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66828204; called by muse, mutect2, varscan2
- GBA2 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 44/87 reads (51%) | catalogued as COSV62305635; called by muse, mutect2, varscan2
- GBP1 | c.645del p.D216Mfs*51 | Frame Shift Del (DEL) | VAF 10/116 reads (9%) | catalogued as COSV65084380; called by mutect2, pindel
- GDF11 | c.1177T>C p.Y393H | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV57689561; called by muse, mutect2, varscan2
- GDF2 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1358534877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFRA2 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs781276745, COSV60778753; called by muse, mutect2, varscan2
- GFRA2 | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60778761; called by muse, mutect2, varscan2
- GGCX | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs144699669, CM090407; called by muse, mutect2, varscan2
- GIMAP2 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV56234925; called by muse, mutect2, varscan2
- GIMAP8 | c.493T>C p.Y165H | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs771211629, COSV56230425; called by muse, mutect2, varscan2
- GINS1 | c.75+1G>A p.X25_splice | Splice Site (SNP) | VAF 138/361 reads (38%) | catalogued as COSV52465167, COSV52467150; called by muse, mutect2, varscan2
- GK2 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV62626566; called by muse, mutect2, varscan2
- GK5 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV67485618; called by muse, mutect2, varscan2
- GLCE | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 103/215 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs749027018, COSV55945045, COSV55947400; called by muse, mutect2, varscan2
- GLRB | c.230-2A>T p.X77_splice | Splice Site (SNP) | VAF 18/154 reads (12%) | catalogued as COSV100029748; called by muse, mutect2, varscan2
- GLS2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); catalogued as rs756555927, COSV61737231; called by muse, mutect2, varscan2
- GLTPD2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as rs777488983, COSV58702417; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 61/167 reads (37%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNL3 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); catalogued as COSV56477266; called by muse, mutect2
- GOLGA1 | c.1461G>T p.E487D | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV63024156; called by muse, mutect2, varscan2
- GOLGA4 | c.4462C>A p.L1488I | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.876); catalogued as COSV62710358; called by muse, mutect2, varscan2
- GOLM1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57414213; called by muse, mutect2, varscan2
- GP2 | c.1310A>C p.Q437P (on ENST00000381362 / NM_001007240.3; = p.Q434P on NM_001502.4) | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV56893114; called by muse, mutect2, varscan2
- GPR158 | c.1196G>A p.C399Y | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66267351, COSV66267896, COSV66268744; called by muse, mutect2
- GPR162 | c.589T>C p.C197R | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV50590231; called by muse, mutect2, varscan2
- GPR173 | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV60234518; called by muse, mutect2, varscan2
- GPR82 | c.875del p.N292Tfs*21 | Frame Shift Del (DEL) | VAF 108/203 reads (53%) | catalogued as rs1158686199, COSV56886767; called by pindel, varscan2
- GPRC5A | c.313T>G p.F105V | Missense Mutation (SNP) | VAF 130/329 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50007573; called by muse, mutect2, varscan2
- GPRC5C | c.931G>A p.G311S (on ENST00000652232; = p.G266S on NM_018653.4) | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs763846707, COSV61236493; called by muse, varscan2
- GPX3 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV59305533; called by muse, mutect2, varscan2
- GRB10 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs745633042, COSV60009685; called by muse, mutect2, varscan2
- GRIA4 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as rs1315970503, COSV99231472; called by muse, mutect2
- GRIK2 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.476); catalogued as COSV59729725; called by muse, mutect2
- GRIPAP1 | c.1023C>G p.S341R | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64551771; called by muse, mutect2, varscan2
- GRM2 | c.2386G>A p.V796M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); catalogued as rs200496822, COSV99623168; called by muse, mutect2, varscan2
- GRSF1 | c.478T>C p.S160P | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99635718; called by muse, varscan2
- GTF2F1 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs147291523; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2458C>G p.L820V (on ENST00000265755 / NM_016328.3; = p.L805V on NM_005685.4) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV56086033; called by muse, mutect2, varscan2
- GTF3C1 | c.1547C>G p.T516S | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV62240555; called by muse, mutect2, varscan2
- GUCY1A1 | c.1254A>C p.Q418H | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56651008; called by muse, mutect2, varscan2
- GUSB | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59221552; called by muse, mutect2, varscan2
- GYG1 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56049345; called by muse, varscan2
- GZMB | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs142224147, COSV53541014; called by muse, mutect2, varscan2
- H4C12 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/364 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs530268862, COSV100694780, COSV62743823; called by muse, mutect2
- HAUS4 | c.911A>G p.D304G | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52827159; called by muse, mutect2, varscan2
- HBS1L | c.2045T>C p.I682T | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV63201058; called by muse, varscan2
- HCLS1 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.622); catalogued as rs147125943; called by muse, mutect2, varscan2
- HCRTR2 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100904362; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 72/164 reads (44%) | catalogued as COSV100625709; called by mutect2, varscan2
- HEATR5A | c.2987A>G p.H996R | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV66340006; called by muse, mutect2, varscan2
- HECA | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62769036; called by muse, mutect2, varscan2
- HERC1 | c.3128A>G p.N1043S | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV71247343; called by muse, mutect2
- HERC2 | c.12532G>A p.G4178S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55319603; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 86/350 reads (25%) | catalogued as rs1449081007; called by mutect2, varscan2
- HEY2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64239750; called by muse, mutect2, varscan2
- HIP1R | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 99/201 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs185463143, COSV53440901; called by muse, mutect2, varscan2
- HIPK2 | c.1913A>G p.Q638R | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100702248; called by muse, mutect2, varscan2
- HIRA | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV54274220; called by muse, mutect2, varscan2
- HK2 | c.938T>C p.M313T | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV51874713; called by muse, mutect2, varscan2
- HLA-DPB1 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.257); catalogued as COSV69602393, COSV69603085; called by muse, mutect2, varscan2
- HNRNPL | c.1010dup p.P338Tfs*56 | Frame Shift Ins (INS) | VAF 20/90 reads (22%) | catalogued as rs767148651; called by mutect2, varscan2
- HOMEZ | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 84/323 reads (26%) | catalogued as COSV62536814; called by muse, mutect2, varscan2
- HOMEZ | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62536825; called by muse, mutect2, varscan2
- HOXD10 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.235); catalogued as rs765114168, COSV99982744; called by muse, mutect2, varscan2
- HOXD3 | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50879975; called by muse, mutect2, varscan2
- HS6ST2 | c.1654A>G p.N552D | Missense Mutation (SNP) | VAF 218/276 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV63712373; called by muse, mutect2, varscan2
- HSD17B2 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV52275567; called by muse, mutect2, varscan2
- HSPA12A | c.1303T>C p.W435R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65021933; called by muse, mutect2, varscan2
- HSPA4L | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs766607334, COSV56544970; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 78/248 reads (31%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HUWE1 | c.3646C>A p.L1216I | Missense Mutation (SNP) | VAF 125/232 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53342646; called by muse, mutect2, varscan2
- HYDIN | c.8972del p.P2991Lfs*28 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs1363667114, COSV59264898; called by pindel, varscan2
- IARS2 | c.560T>C p.F187S | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56959151; called by muse, mutect2, varscan2
- IARS2 | c.1582T>C p.W528R | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56959159; called by muse, mutect2, varscan2
- IBTK | c.1859T>C p.V620A | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV60392348; called by muse, mutect2, varscan2
- ICA1L | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64173164; called by muse, mutect2, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs771790236; called by mutect2, varscan2
- IFFO1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs747627725, COSV59110286; called by muse, mutect2, varscan2
- IFIH1 | c.1757A>G p.E586G | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as rs777933362, COSV55124899, COSV55126049; called by muse, mutect2, varscan2
- IFNB1 | c.475T>C p.Y159H | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.503); catalogued as COSV66525284; called by muse, mutect2, varscan2
- IFRD1 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV50043993; called by muse, mutect2, varscan2
- IFT122 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV51444417; called by muse, mutect2, varscan2
- IFT172 | c.40-1G>T p.X14_splice | Splice Site (SNP) | VAF 38/114 reads (33%) | catalogued as COSV53132659; called by muse, mutect2, varscan2
- IGF2 | c.311G>A p.R104H (on ENST00000434045 / NM_001127598.3; = p.R48H on NM_000612.6) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778465733, COSV56098326; called by muse, mutect2, varscan2
- IGF2BP1 | c.1489T>G p.S497A | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV51730599; called by muse, mutect2, varscan2
- IGF2R | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs8191704; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 49/118 reads (42%) | catalogued as rs760021495; called by mutect2, varscan2
- IGF2R | c.5862A>G p.I1954M | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV63628374; called by muse, mutect2, varscan2
- IGHD1-7 | c.4A>G p.I2V | Missense Mutation (SNP) | VAF 162/464 reads (35%) | PolyPhen possibly damaging (0.817); catalogued as rs554047854; called by muse, mutect2, varscan2
- IGHM | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 110/226 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs375873260; called by muse, mutect2, varscan2
- IGHV3-23 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.263); catalogued as rs1343555427; called by muse, mutect2, varscan2
- IGSF9B | c.2575G>A p.V859M | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs756787214, COSV58066584, COSV58071923; called by muse, mutect2, varscan2
- IKBIP | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV54489358; called by muse, mutect2, varscan2
- IKBKB | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 64/341 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100645699; called by muse, mutect2, varscan2
- IL16 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335286153, COSV57262589; called by muse, mutect2, varscan2
- IL17RE | c.181T>C p.W61R | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs762990550, COSV55967772; called by muse, mutect2, varscan2
- IL1RAP | c.864del p.K288Nfs*15 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as rs780458834, COSV50762431; called by pindel, varscan2
- IL1RN | c.383C>T p.S128L (on ENST00000409930 / NM_173842.3; = p.S110L on NM_000577.5) | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV52080487; called by muse, mutect2, varscan2
- IL9R | c.1375G>T p.G459* | Nonsense Mutation (SNP) | VAF 30/120 reads (25%) | catalogued as COSV54899234; called by muse, mutect2, varscan2
- ILVBL | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767342989, COSV54619039; called by muse, mutect2, varscan2
- ILVBL | c.336C>T p.S112= | Splice Region (SNP) | VAF 51/123 reads (41%) | catalogued as rs765311341, COSV54619049; called by muse, mutect2, varscan2
- IMPDH2 | c.908A>T p.N303I | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58707748; called by muse, mutect2, varscan2
- ING2 | c.445T>C p.S149P | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.502); catalogued as COSV56564056; called by muse, mutect2, varscan2
- INSR | c.2387G>T p.R796M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.243); catalogued as COSV57161338; called by muse, mutect2, varscan2
- INTS1 | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67177159; called by muse, mutect2, varscan2
- INTS4 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV59017656; called by muse, mutect2, varscan2
- INVS | c.3017-1G>T p.X1006_splice | Splice Site (SNP) | VAF 13/169 reads (8%) | catalogued as COSV99317535; called by muse, mutect2
- IPO4 | c.2129A>G p.H710R | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as COSV61016348; called by muse, mutect2, varscan2
- IQCA1 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773494914, COSV54500365; called by muse, mutect2, varscan2
- IRAK1 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV64110634; called by muse, mutect2, varscan2
- IRF1 | c.718-1G>T p.X240_splice | Splice Site (SNP) | VAF 10/102 reads (10%) | catalogued as COSV55377067; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 66/92 reads (72%) | catalogued as rs780982673; called by mutect2, varscan2
- ITGB3 | c.1543del p.R515Gfs*154 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as COSV101457728; called by mutect2, varscan2
- JCAD | c.3082A>G p.R1028G | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV64759174; called by muse, mutect2, varscan2
- JMJD1C | c.2357C>A p.P786Q | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV101232416, COSV67857852; called by muse, mutect2
- KALRN | c.2212A>C p.S738R | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53760750; called by muse, mutect2, varscan2
- KAT5 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100383917; called by muse, mutect2
- KATNAL1 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as rs1216516815, COSV66063095; called by muse, mutect2, varscan2
- KBTBD3 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.412); catalogued as COSV73241353; called by muse, mutect2, varscan2
- KBTBD6 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776829429, COSV65271174; called by muse, mutect2, varscan2
- KCNB2 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 36/124 reads (29%) | catalogued as COSV73049818; called by muse, varscan2
- KCNJ2 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs895505794, COSV54660976; called by muse, mutect2, varscan2
- KCNK5 | c.1085T>C p.L362P | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as COSV63988811; called by muse, mutect2, varscan2
- KCNT1 | c.2187-1G>A p.X729_splice (on ENST00000488444; = p.X748_splice on NM_020822.3) | Splice Site (SNP) | VAF 28/128 reads (22%) | catalogued as rs1412885784, COSV53699957, COSV53707908; called by muse, varscan2
- KCTD18 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.011); catalogued as COSV63344211; called by muse, mutect2, varscan2
- KCTD19 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100430927; called by muse, mutect2, varscan2
- KCTD19 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV58572380; called by muse, mutect2, varscan2
- KDM4C | c.2303C>T p.T768M | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs776521442, COSV67185872; called by muse, mutect2, varscan2
- KEL | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV62334445, COSV62335304; called by muse, mutect2, varscan2
- KHNYN | c.1922A>G p.Q641R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV52159963; called by muse, mutect2, varscan2
- KIAA0232 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 114/306 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.605); catalogued as rs374592929; called by muse, mutect2, varscan2
- KIAA0408 | c.1231T>G p.C411G | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1416576585, COSV100846919; called by muse, mutect2, varscan2
- KIAA0408 | c.245C>A p.P82Q | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV64106257; called by muse, mutect2, varscan2
- KIAA1109 | c.3830C>T p.A1277V | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV52669653; called by muse, mutect2, varscan2
- KIAA1549 | c.1736C>A p.P579Q | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs368176243, COSV99650791; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs752375544, COSV54318481; called by mutect2, pindel, varscan2
- KIAA1549L | c.4436G>A p.S1479N (on ENST00000321505; = p.S1776N on NM_012194.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as COSV58586489; called by muse, mutect2, varscan2
- KIAA1755 | c.3446C>T p.A1149V | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV54075752; called by muse, mutect2, varscan2
- KIDINS220 | c.900G>T p.Q300H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1265766448, COSV56752499; called by muse, mutect2, varscan2
- KIF16B | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV61705101; called by muse, mutect2, varscan2
- KIF18A | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 130/312 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54182588; called by muse, mutect2, varscan2
- KIF18B | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59272441; called by muse, mutect2
- KIF1A | c.1507A>C p.M503L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV57487110; called by muse, mutect2, varscan2
- KIF21A | c.2285A>G p.D762G (on ENST00000361418 / NM_001378440.1; = p.D749G on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/362 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1196503556, COSV62770309; called by muse, mutect2
- KIF21B | c.2384A>T p.E795V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59756207; called by muse, mutect2
- KIF3A | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV66414165; called by muse, mutect2, varscan2
- KIFC3 | c.1802A>C p.D601A | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV65549958; called by muse, mutect2, varscan2
- KIRREL2 | c.665G>C p.S222T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV52875791; called by muse, mutect2, varscan2
- KIRREL2 | c.1617C>A p.A539= | Splice Region (SNP) | VAF 9/115 reads (8%) | catalogued as COSV99383994; called by muse, mutect2
- KIRREL3 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV69384131; called by muse, mutect2, varscan2
- KLF1 | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as CM121776, COSV53434861; called by muse, mutect2, varscan2
- KLF3 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV54710504; called by muse, mutect2, varscan2
- KLF8 | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63847668; called by muse, mutect2, varscan2
- KLHL18 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 52/148 reads (35%) | catalogued as COSV51745116; called by muse, mutect2, varscan2
- KLHL23 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs1322865156, COSV55866799; called by muse, mutect2, varscan2
- KLK1 | c.784T>A p.S262T | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV56826628; called by muse, mutect2, varscan2
- KLK11 | c.710del p.G237Afs*43 (on ENST00000594768 / NM_144947.3; = p.G205Afs*43 on NM_006853.3) | Frame Shift Del (DEL) | VAF 30/87 reads (34%) | catalogued as COSV100011071; called by mutect2, pindel, varscan2
- KLK12 | c.576del p.Q193Rfs*51 (on ENST00000319590 / NM_001370127.1; = p.Q193Rfs*? on NM_019598.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as COSV99141988; called by mutect2, varscan2
- KMT2B | c.4040A>G p.D1347G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV55859899; called by muse, mutect2, varscan2
- KMT2B | c.5554G>A p.A1852T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.075); catalogued as rs746346674, COSV55859907; ClinVar: benign; called by muse, mutect2, varscan2
- KMT2B | c.7244G>A p.R2415H | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.167); catalogued as COSV55820347; called by muse, mutect2, varscan2
- KMT2C | c.5243A>C p.E1748A | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51430781; called by muse, mutect2, varscan2
- KMT2E | c.3755+2T>C p.X1252_splice | Splice Site (SNP) | VAF 18/42 reads (43%) | catalogued as COSV57572248; called by muse, mutect2, varscan2
- KMT5B | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 80/182 reads (44%) | catalogued as COSV58565596; called by muse, mutect2, varscan2
- KNSTRN | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV51104735; called by muse, mutect2, varscan2
- KRT33A | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs548761610, COSV50366471, COSV50371352; called by muse, mutect2, varscan2
- KRT73 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs759632289, COSV59838867; called by muse, mutect2, varscan2
- KRT74 | c.1427C>A p.P476H | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV59770517, COSV59771094; called by muse, mutect2, varscan2
- KRT77 | c.758+2T>C p.X253_splice | Splice Site (SNP) | VAF 106/261 reads (41%) | catalogued as COSV59239410; called by muse, mutect2, varscan2
- KRT86 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs757946783, COSV53292299; called by muse, mutect2, varscan2
- KRTAP10-4 | c.949T>G p.C317G | Missense Mutation (SNP) | VAF 40/381 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV59959148; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 49/126 reads (39%) | catalogued as rs750491454; called by mutect2, varscan2
- L1TD1 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1392018704, COSV63133415; called by muse, mutect2, varscan2
- LAGE3 | c.272G>T p.R91M | Missense Mutation (SNP) | VAF 124/156 reads (79%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV100635689, COSV62074175; called by muse, mutect2, varscan2
- LAMA1 | c.4666T>C p.C1556R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67535647; called by muse, mutect2, varscan2
- LAMA3 | c.947+1G>A p.X316_splice | Splice Site (SNP) | VAF 71/206 reads (34%) | catalogued as rs1274774560, COSV58067149; called by muse, mutect2, varscan2
- LAMB2 | c.5252G>A p.R1751Q | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.54); catalogued as COSV59732794; called by muse, mutect2, varscan2
- LAMB2 | c.3256C>T p.L1086F | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs761458514, COSV59732800; called by muse, mutect2, varscan2
- LAMC2 | c.3452A>G p.Q1151R | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV51454754; called by muse, mutect2, varscan2
- LAMP3 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 104/1094 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774368709, COSV99660544; called by muse, mutect2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 138/226 reads (61%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCAT | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV50452629; called by muse, mutect2, varscan2
- LDHB | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV63364573; called by mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 56/152 reads (37%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LEPR | c.3270T>A p.S1090R | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs899012369, COSV62747128; called by muse, mutect2, varscan2
- LGR6 | c.1278G>A p.K426= (on ENST00000367278 / NM_001017403.1; = p.K374= on NM_021636.3) | Splice Region (SNP) | VAF 73/254 reads (29%) | catalogued as COSV55155791; called by muse, mutect2, varscan2
- LGR6 | c.1532C>A p.P511H (on ENST00000367278 / NM_001017403.1; = p.P459H on NM_021636.3) | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as COSV55164023, COSV99706904; called by muse, mutect2
- LIN7A | c.458A>C p.D153A | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54020520; called by muse, varscan2
- LIN7C | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV99536217; called by muse, mutect2, varscan2
- LINGO1 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 89/213 reads (42%) | catalogued as COSV62436780; called by muse, mutect2, varscan2
- LIPE | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 157/356 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.205); catalogued as COSV54921588, COSV99734110; called by muse, mutect2, varscan2
- LMBRD2 | c.1119T>C p.F373= | Splice Region (SNP) | VAF 27/67 reads (40%) | catalogued as COSV56949546; called by muse, mutect2, varscan2
- LMNB1 | c.550T>G p.L184V | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV99745904; called by muse, mutect2
- LMO7 | c.3740G>T p.R1247M (on ENST00000357063; = p.R928M on NM_005358.5) | Missense Mutation (SNP) | VAF 211/480 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV58531116, COSV58534304; called by muse, mutect2, varscan2
- LOXL2 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.289); catalogued as rs1232945590, COSV66691209; called by muse, mutect2, varscan2
- LOXL4 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 106/235 reads (45%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.529); catalogued as COSV53256228; called by muse, mutect2, varscan2
- LPAR1 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.044); catalogued as COSV62688349; called by muse, mutect2, varscan2
- LRFN5 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV53252803; called by muse, mutect2, varscan2
- LRP1 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54508695; called by muse, mutect2, varscan2
- LRRC17 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV50864502; called by muse, mutect2
- LRRC41 | c.556A>G p.R186G | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1270068202, COSV58439669; called by muse, mutect2
- LRRC66 | c.975G>T p.Q325H | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as COSV58633232, COSV58634709; called by muse, mutect2, varscan2
- LRRC71 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759314364, COSV61656170; called by muse, mutect2, varscan2
- LRRC8A | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV52185351; called by muse, mutect2, varscan2
- LRRC8A | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52185361; called by muse, mutect2, varscan2
- LTBP2 | c.5345A>G p.N1782S | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.574); catalogued as COSV56207168; called by muse, mutect2, varscan2
- LTBP4 | c.4772C>T p.A1591V (on ENST00000308370 / NM_001042544.1; = p.A1554V on NM_003573.2) | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV52580230; called by muse, mutect2, varscan2
- LUC7L3 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1235636727, COSV53586572; called by muse, mutect2, varscan2
- LUZP2 | c.469dup p.I157Nfs*18 | Frame Shift Ins (INS) | VAF 46/153 reads (30%) | catalogued as rs766421606; called by mutect2, varscan2
- LYG1 | c.334-1G>T p.X112_splice | Splice Site (SNP) | VAF 23/74 reads (31%) | catalogued as COSV57915381; called by muse, mutect2, varscan2
- LYL1 | c.586A>G p.M196V | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV53399977, COSV53400910; called by muse, varscan2
- LYST | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV67706220, COSV67708680; called by muse, mutect2, varscan2
- LZTS2 | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64651424; called by muse, mutect2, varscan2
- MAGI1 | c.3259A>C p.T1087P (on ENST00000402939 / NM_001033057.2; = p.T1116P on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 213/575 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.237); catalogued as COSV100441003; called by muse, mutect2, varscan2
- MAK16 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64078228; called by muse, varscan2
- MAL2 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 42/784 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV99411001; called by muse, mutect2
- MAP10 | c.2710C>T p.L904F | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.584); catalogued as COSV101406518, COSV69363371, COSV69364425; called by muse, mutect2, varscan2
- MAP1A | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.286); catalogued as COSV100288662; called by muse, mutect2, varscan2
- MAP1LC3C | c.155del p.P52Rfs*13 | Frame Shift Del (DEL) | VAF 27/100 reads (27%) | catalogued as rs762632974, COSV61803913; called by mutect2, pindel, varscan2
- MAP2K3 | c.124del p.R42Gfs*24 (on ENST00000342679 / NM_145109.3; = p.R13Gfs*24 on NM_002756.4) | Frame Shift Del (DEL) | VAF 28/161 reads (17%) | catalogued as rs1567665648, COSV57561353; called by mutect2, pindel, varscan2
- MAP3K10 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1389532844, COSV53421754; called by muse, mutect2, varscan2
- MAP3K11 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58418438, COSV58419266; called by muse, mutect2
- MAP3K4 | c.531dup p.S178Ifs*9 | Frame Shift Ins (INS) | VAF 44/107 reads (41%) | catalogued as rs750651844; called by mutect2, varscan2
- MAPK15 | c.224G>C p.S75T | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV100567881; called by muse, mutect2
- MAPKAPK3 | c.424+2T>C p.X142_splice | Splice Site (SNP) | VAF 58/452 reads (13%) | catalogued as COSV63597219; called by muse, mutect2, varscan2
1,558 further variants in this file (1,042 protein-altering or splice-affecting, 471 silent, 45 other) are not listed here.
